Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A77Q, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A77Q-01A (Primary Tumor).

[page 1 of 4]
Surgical Report

**Specimen
Description**

Patient Name:

Account #

Accession #: [REDACTED]

Hospital

Hospital ID:

DOB:

Age/Sex:

I F

Attending Physician

Ordering Physician

Performing Physician

Collection Date:

Hospital of Origin

Copy to

QC Pathologist:

ICD-O-3

Adenocarcinoma NOS 8140/3

**Site C&P
Pancreas, head C25.0
path**

Pancreas NOS C25.9

gn 8/19/13

FINAL PATHOLOGIC DIAGNOSIS:

A. gallbladder, cholecystectomy:

Chronic cholecystitis.

B. peri-portal lymph node, excision:

One lymph node, negative for metastatic disease.

Frozen section diagnosis confirmed.

C. perigastric lymph node, excision:

One lymph node, negative for metastatic disease.

Frozen section diagnosis confirmed.

D. distal margin of pancreas, biopsy:

Severe chronic pancreatitis, malignancy not identified.

Frozen section diagnosis confirmed.

E. pancreas and duodenum, Whipple:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.

2. Histologic grade: 2, moderately differentiated.

3. Tumor site: Pancreas with extension into ampulla.

4. Tumor size: 2.8 x 2.2 x 1.7 CM.

5. Microscopic tumor extension:

a. Tumor invades: Ampulla.

6. Treatment effect: Not identified.

7. Lymphovascular space invasion: Not identified.

8. Perineural invasion: Not identified.

Surgical Margin Status:

1. Margins uninvolved by invasive carcinoma: Uncinate process, bile duct, pancreatic resection, posterior and superior soft tissue.

a. Distance of invasive carcinoma from closest margin: 0.1 CM.

b. Specify margin (if possible): Anterior and inferior soft tissue margins.

2. Margin(s) involved by invasive carcinoma: None.

Lymph Node Status:

1. Total number of lymph nodes received: 19.

2. Total number of lymph nodes involved: One.

Other:

1. pTNM stage: pT3N1.

[page 2 of 4]
2. Other significant findings: Chronic pancreatitis.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: Pancreatic cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Gallbladder

B. Periportal lymph node frozen section

C. Perigastric frozen section

D. Distal margin of pancreas

E. Pancreas/duodenum stitch in deep margin/inked pancreatic transection margin

CODES:

88304

88305

88331

88305

88331

88305

88331

88309

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time: [REDACTED]

GROSS DESCRIPTION:

A. Received in formalin labeled [REDACTED] and '#1 gallbladder' is a 6.7 x 3.2 x 1.9 cm intact gallbladder with a 0.2 cm cystic duct. The serosa is smooth and tan-green. The mucosa is velvety and tan-green. The lumen contains green bile. The bile and formalin are filtered through a fine mesh structure and no choleliths are identified in the lumen or the specimen container. The wall thickness averages 0.1 cm. The specimen is sectioned and representative sections are submitted in one cassette

B. Received labeled [REDACTED] and '#2 periportal lymph node' is a 2.3 x 1.8 x 0.5 cm irregular tan firm tissue consistent with a probable lymph node. The cut surface consists of lobulated tan soft tissue. The specimen is bisected and submitted in its entirety for frozen section and the frozen section residue is submitted in blocks 1 and 2 labeled

C. Received labeled [REDACTED] and '#3 perigastric lymph node' is a 0.7 x 0.5 x 0.2 cm irregular tan firm tissue consistent with a probable lymph node with attached adipose tissue which is submitted in toto for frozen section and the frozen section residue is submitted in one cassette labeled

D. Received labeled [REDACTED] and '#4 distal margin of pancreas' is a 2.1 x 1.7 x 0.3 cm irregular tan-yellow lobulated soft tissue, which is submitted in toto for frozen section and the frozen section residue is submitted in one

[page 3 of 4]
E. Received in formalin labeled

pancreas/duodenum slitch in deep margin, ink marking pancreatic resection margin' is a Whipple specimen consisting of a 8.9 cm segment of stomach with a minimal amount of attached mesentery, a 13.6 cm segment of duodenum, a 4.8 x 2.5 x 2.0 cm portion of pancreas and a 1.2 cm segment of common bile duct. There is a very minimal amount of attached fibroadipose tissue on the duodenum and pancreas. There is a suture designating the deep margin and ink on the pancreatic resection margin.

The outer surface of the pancreas is shaggy and tan. The cut surface of the pancreas consists of a 2.8 x 2.2 x 1.7 cm ill-defined slightly cystic gray-white mass, 2.2 cm and 2.0 cm from the pancreatic resection margin and common bile duct margin, respectively. The lesion abuts the uncinate process, anterior, posterior and inferior pancreatic soft tissue margins and is 2.2 cm from the superior pancreatic soft tissue margin. The lesion appears to involve the ampulla of Vater, but does not involve the duodenal mucosa.

The remainder of the cut surface of the pancreas consists of lobulated tan-yellow soft tissue. No additional lesions are identified.

The gastric serosa is smooth and tan-pink. The mucosa is tan-pink with the normal folds. No mucosal masses are identified. The inner circumference averages 8.8 cm and the wall thickness averages 0.5 cm.

The duodenal serosa is smooth to shaggy and tan-pink. The mucosa is tan-pink with the normal folds. No mucosal masses are identified. The inner circumference ranges from 5.2 cm to 11.2 cm and the wall thickness averages 0.2 cm.

There are multiple irregular tan-firm tissues consistent with probable lymph nodes ranging from 0.2 x 0.2 x 0.1 cm to 1.8 x 0.5 x 0.6 cm.

Also received in the same container is a 2.0 x 1.4 x 0.7 cm tan firm tissue consistent with probable lymph node. The cut surface is tan-yellow.

The specimen is inked, sectioned and representative sections are submitted as labeled: block 1, gastric and duodenal margins (en face); block 2, pancreatic resection margin (en face); block 3, common bile duct (en face); block 4, ampulla of Vater; block 5, lesion to uncinate process (perpendicular); block 6, lesion to anterior pancreatic soft tissue; block 7, lesion to posterior pancreatic soft tissue; block 8, lesion to inferior pancreatic soft tissue; block 9, lesion; block 10, superior pancreatic soft tissue (perpendicular); block 11, uninvolved pancreatic parenchyma; block 12, pylorus; blocks 13 and 14, five whole perigastric probable lymph nodes in each; blocks 15 and 16, two whole peripancreatic probable lymph nodes in each; block 17, one peripancreatic lymph node, trisected; block 18, one peripancreatic lymph node, serially sectioned; blocks 19 and 20, peripancreatic and duodenal adipose tissue, entirely submitted; block 21, additional tissue, bisected. The blocks labeled

Also received in the same container is a blue, yellow and green cassette labeled

for

[page 4 of 4]
INTRA-PROCEDURE CONSULTATION:

FROZEN SECTION DIAGNOSES:

Part B: Tumor not identified.

Part C: Tumor not identified.

Both of those diagnoses are

Part D: Negative for tumor

Prior Malignancy History	Vagina, Thyroid ✓	1
Reviewed (Initials):	KML	

Source: NCI Genomic Data Commons file 06309ea5-aa71-4f48-b750-abd9c96d0d63 (TCGA-HZ-A77Q.D550175A-9593-4283-94D5-91268C8D7799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).